Somatic mutation profile of tumor specimen TARGET-10-PAPIEW-09A (aliquot TARGET-10-PAPIEW-09A-01D) from TARGET case TARGET-10-PAPIEW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,059 days).
Specimen TARGET-10-PAPIEW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b50cc9d-c024-4db1-bc5f-51b325326894.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIEW-10A (Blood Derived Normal), aliquot TARGET-10-PAPIEW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7989ab8-aea3-4226-8273-d9658ca93518

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DCAF4L2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs757957851, COSV60476958; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs757261707, COSV58544278; called by muse, mutect2, varscan2
- GRM1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768250872, COSV51110462, COSV51132186; called by muse, mutect2, varscan2
- KCNH6 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs768097692; called by muse, mutect2, varscan2
- LAMA1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532355831, COSV67539693; called by muse, mutect2, varscan2
- PCDH17 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV64971920; called by muse, mutect2, varscan2
- SLC13A1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.786); catalogued as rs772776032, COSV52008597; called by muse, mutect2, varscan2
- CFAP97 | c.806T>C p.F269S | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CTCF | c.1727dup p.N576Kfs*20 | Frame Shift Ins (INS) | VAF 31/82 reads (38%) | called by mutect2, pindel, varscan2
- FLG | c.5519G>T p.G1840V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASA2 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- STAC2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL19A1 | c.69C>T p.S23= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs375883070; called by muse, mutect2, varscan2
- GCOM1 | c.462G>A p.S154= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs762492034; called by muse, mutect2, varscan2
- GLIS3 | c.159G>A p.A53= | Silent (SNP) | VAF 57/118 reads (48%) | catalogued as rs770666979; called by muse, mutect2, varscan2
- ZBTB42 | c.441C>T p.T147= | Silent (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- MYH11 | c.2058+63C>T | Intron (SNP) | VAF 18/55 reads (33%) | catalogued as rs747490565; called by muse, mutect2, varscan2
- PDPN | c.67+30G>A | Intron (SNP) | VAF 7/97 reads (7%) | catalogued as COSV53850862; called by muse, mutect2
- ZWILCH | c.*1664T>C | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
